Somatic mutation profile of tumor specimen HCM-WCMC-1359-C34-01A (aliquot HCM-WCMC-1359-C34-01A-05D-A937-36) from HCMI case HCM-WCMC-1359-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,094 days).
Specimen HCM-WCMC-1359-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39cb748e-f75d-4015-8c0d-4941b387350c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1359-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-1359-C34-10A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5906951a-640e-46fa-be9d-79c3a1fca8fc

The open-access MAF lists 166 somatic variants for this specimen: 114 protein-altering or splice-affecting, 45 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 45, Nonsense Mutation 11, Intron 4, Frame Shift Del 3, 5'Flank 1, Nonstop Mutation 1, In Frame Del 1, 3'UTR 1, Splice Site 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 205/301 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1840A>T p.M614L | Missense Mutation (SNP) | VAF 161/421 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99202481; called by muse, mutect2, varscan2
- ADAM12 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64107034; called by muse, mutect2, varscan2
- ADAMTS19 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99184486; called by muse, mutect2, varscan2
- ADAMTS20 | c.2317C>G p.L773V | Missense Mutation (SNP) | VAF 76/263 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV101166293; called by muse, mutect2, varscan2
- AGTPBP1 | c.1565C>T p.S522L (on ENST00000357081 / NM_001330701.2; = p.S482L on NM_015239.2) | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1420730699; called by muse, mutect2, varscan2
- ANKRD11 | c.6005C>T p.S2002F | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV99039934; called by muse, mutect2, varscan2
- ASB16 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 118/166 reads (71%) | catalogued as rs780082937; called by muse, mutect2, varscan2
- ASTN2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs764391655; called by muse, varscan2
- BAHCC1 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 166/429 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as rs782392409; called by muse, mutect2, varscan2
- CASP5 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755827751; called by muse, mutect2, varscan2
- CDKN2A | c.131dup p.Y44* | Nonsense Mutation (INS) | VAF 57/159 reads (36%) | catalogued as rs730881673; called by mutect2, pindel, varscan2
- CELSR3 | c.9250C>T p.R3084* | Nonsense Mutation (SNP) | VAF 70/265 reads (26%) | catalogued as rs759724759, COSV99373332; called by muse, mutect2, varscan2
- CXCL16 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 191/291 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV53411780; called by muse, mutect2, varscan2
- DCAF4L1 | c.1104C>A p.F368L | Missense Mutation (SNP) | VAF 148/294 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV60786749; called by muse, mutect2, varscan2
- DNAJB5 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 120/277 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs761475982; called by muse, mutect2, varscan2
- ERBB2 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 196/505 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs758365405, COSV54066593; called by muse, mutect2, varscan2
- FAM171A1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 153/419 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs765007765; called by muse, mutect2, varscan2
- FAT3 | c.9739G>A p.E3247K | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs186585296; called by muse, mutect2, varscan2
- FBXO31 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs913359928; called by muse, mutect2
- FLNC | c.4274G>T p.G1425V | Missense Mutation (SNP) | VAF 219/404 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57949464; called by muse, mutect2, varscan2
- H2AX | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 151/360 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99598061, COSV99598297; called by muse, mutect2, varscan2
- HJURP | c.2013_2024del p.G672_D675del | In Frame Del (DEL) | VAF 120/322 reads (37%) | catalogued as rs767162725; called by mutect2, varscan2
- IVL | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 98/557 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.66); catalogued as rs985873590, COSV100908321; called by muse, mutect2
- KCNH3 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 138/343 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99235234; called by muse, mutect2, varscan2
- LHFPL3 | c.56C>G p.S19W | Missense Mutation (SNP) | VAF 123/481 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV67809950; called by muse, mutect2, varscan2
- LRRC9 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355598297; called by muse, mutect2, varscan2
- MED12L | c.1364C>G p.T455S | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV56387477; called by muse, mutect2, varscan2
- OBSCN | c.8717C>T p.T2906I | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs933866975; called by muse, mutect2, varscan2
- OR6C76 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 97/213 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60389640; called by muse, mutect2, varscan2
- PLEKHG6 | c.992G>C p.R331P | Missense Mutation (SNP) | VAF 141/366 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs370748302; called by muse, mutect2, varscan2
- PSG6 | c.708G>C p.P236= | Splice Region (SNP) | VAF 83/190 reads (44%) | catalogued as COSV51832634; called by muse, varscan2
- PTCHD4 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59776858, COSV59798131; called by muse, mutect2, varscan2
- RCSD1 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV63259595; called by muse, mutect2, varscan2
- RNF216 | c.2524G>A p.D842N (on ENST00000425013 / NM_207116.3; = p.D899N on NM_207111.4) | Missense Mutation (SNP) | VAF 176/470 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66288812; called by muse, mutect2, varscan2
- RNF43 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 175/424 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV68457329; called by muse, mutect2, varscan2
- RP1L1 | c.5968G>C p.E1990Q | Missense Mutation (SNP) | VAF 169/443 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.734); catalogued as COSV66758181; called by muse, mutect2, varscan2
- SHOC2 | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs767570209, COSV54621772; called by muse, mutect2, varscan2
- SLC24A3 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs1286917670; called by muse, mutect2, varscan2
- SLC44A3 | c.373C>T p.L125F (on ENST00000271227 / NM_001114106.3; = p.L77F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/293 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99598482; called by muse, mutect2, varscan2
- SPACA1 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV52759079; called by muse, mutect2, varscan2
- STK11 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 166/240 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100479383, COSV58820651; called by muse, mutect2, varscan2
- STPG2 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 31/201 reads (15%) | catalogued as COSV99757844; called by muse, mutect2, varscan2
- TIAM1 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 148/432 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV54558946; called by muse, mutect2, varscan2
- ACOX3 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMPD2 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 67/342 reads (20%) | called by muse, mutect2, varscan2
- ASH1L | c.5191G>C p.E1731Q | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ASPSCR1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP5F1A | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 155/455 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GNT8 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 158/409 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- BLM | c.2343G>C p.E781D | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- BTNL9 | c.110-1G>T p.X37_splice | Splice Site (SNP) | VAF 67/166 reads (40%) | called by muse, mutect2, varscan2
- C8B | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CDKL2 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHPF2 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 288/469 reads (61%) | called by muse, mutect2, varscan2
- CIT | c.3297G>C p.E1099D | Missense Mutation (SNP) | VAF 150/396 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- COX5B | c.389G>T p.*130Lext*20 | Nonstop Mutation (SNP) | VAF 143/392 reads (36%) | called by muse, mutect2, varscan2
- CRELD1 | c.1067C>G p.S356* | Nonsense Mutation (SNP) | VAF 70/264 reads (27%) | called by muse, varscan2
- CRELD1 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, varscan2
- CRELD1 | c.1217C>G p.S406* | Nonsense Mutation (SNP) | VAF 70/308 reads (23%) | called by muse, mutect2, varscan2
- CX3CL1 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- DCAF1 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DHX30 | c.1099G>C p.V367L (on ENST00000445061 / NM_138615.3; = p.V328L on NM_014966.3) | Missense Mutation (SNP) | VAF 122/229 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK6 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 160/232 reads (69%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); called by muse, varscan2
- DUSP8 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM184A | c.2151A>T p.Q717H | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FSIP2 | c.2145A>G p.I715M | Missense Mutation (SNP) | VAF 128/364 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- HS3ST2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 202/388 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- IL12B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 150/324 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IVNS1ABP | c.770del p.K257Sfs*11 | Frame Shift Del (DEL) | VAF 57/162 reads (35%) | called by mutect2, pindel, varscan2
- KCNJ15 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 184/456 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KCNN4 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KEAP1 | c.1187dup p.Y396* | Nonsense Mutation (INS) | VAF 139/270 reads (51%) | called by mutect2, pindel, varscan2
- KIAA0825 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF3A | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KMT2B | c.3488A>G p.K1163R | Missense Mutation (SNP) | VAF 147/356 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LMOD3 | c.1338C>G p.F446L | Missense Mutation (SNP) | VAF 202/403 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPCAT1 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 179/497 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LPIN2 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 62/417 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC39 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC8C | c.2171A>G p.E724G | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- LRRIQ3 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAGI3 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 131/290 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAP7D2 | c.2038A>G p.T680A | Missense Mutation (SNP) | VAF 134/164 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- MLLT10 | c.2867G>A p.G956E (on ENST00000307729 / NM_001195626.3; = p.G972E on NM_004641.3) | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OPA1 | c.2911G>T p.D971Y (on ENST00000361510 / NM_130837.3; = p.D916Y on NM_015560.3) | Missense Mutation (SNP) | VAF 144/391 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR12D3 | c.651C>G p.F217L | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5H2 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PALB2 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB14 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 102/397 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PCDHB8 | c.1204T>C p.Y402H | Missense Mutation (SNP) | VAF 105/1347 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- PLA2G7 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 50/181 reads (28%) | called by muse, mutect2, varscan2
- PRKAR1B | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PRRT3 | c.2554del p.R852Gfs*37 | Frame Shift Del (DEL) | VAF 76/300 reads (25%) | called by mutect2, pindel, varscan2
- RSF1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR3 | c.14337G>C p.Q4779H (on ENST00000389232; = p.Q4780H on NM_001036.6) | Missense Mutation (SNP) | VAF 108/328 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A41 | c.297_325del p.A100Hfs*53 | Frame Shift Del (DEL) | VAF 56/148 reads (38%) | called by mutect2, pindel, varscan2
- TCEANC | c.535G>C p.E179Q (on ENST00000380600 / NM_001297563.2; = p.E209Q on NM_152634.4) | Missense Mutation (SNP) | VAF 101/160 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TIAM2 | c.731G>C p.S244T | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TICRR | c.2167G>T p.V723L | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- TMEM121 | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPRSS5 | c.989C>G p.P330R | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNIK | c.2977G>C p.D993H | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TNIK | c.1976G>A p.S659N | Missense Mutation (SNP) | VAF 138/386 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TPD52L1 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRAF3IP3 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 59/416 reads (14%) | called by muse, mutect2, varscan2
- TRIM51 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRIP13 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 173/490 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TTC3 | c.1266dup p.D423* | Frame Shift Ins (INS) | VAF 84/267 reads (31%) | called by mutect2, pindel, varscan2
- VAT1L | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNT10A | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 135/322 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- WNT9B | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 184/485 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- XPR1 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZGPAT | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 145/376 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC099489.1 | c.3138C>A p.I1046= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs948638746; called by muse, mutect2, varscan2
- ARHGAP23 | c.4221C>T p.T1407= | Silent (SNP) | VAF 143/322 reads (44%) | called by muse, mutect2, varscan2
- ATN1 | c.2352C>T p.F784= | Silent (SNP) | VAF 134/433 reads (31%) | catalogued as rs1418627045, COSV100755921, COSV63112947; called by muse, varscan2
- BHMG1 | c.1104C>T p.F368= | Silent (SNP) | VAF 160/256 reads (63%) | catalogued as COSV71837285; called by muse, mutect2, varscan2
- CAMK1D | c.687C>A p.L229= | Silent (SNP) | VAF 140/379 reads (37%) | called by muse, mutect2, varscan2
- CD244 | c.363C>T p.F121= | Silent (SNP) | VAF 44/286 reads (15%) | catalogued as rs774752476, COSV59241003; called by muse, varscan2
- CDK5RAP3 | c.225C>G p.L75= | Silent (SNP) | VAF 131/332 reads (39%) | called by muse, mutect2, varscan2
- CLIP2 | c.540G>T p.L180= | Silent (SNP) | VAF 124/346 reads (36%) | catalogued as COSV56285477; called by muse, mutect2, varscan2
- CLIP2 | c.2391C>T p.V797= | Silent (SNP) | VAF 106/282 reads (38%) | catalogued as rs1298881144; called by muse, mutect2, varscan2
- CSMD2 | c.2469C>T p.H823= | Silent (SNP) | VAF 120/289 reads (42%) | catalogued as rs774509837, COSV53969756; called by muse, mutect2, varscan2
- CYP11A1 | c.1077G>A p.A359= | Silent (SNP) | VAF 163/401 reads (41%) | catalogued as rs987318812, COSV51431482; called by muse, mutect2, varscan2
- CYP2S1 | c.888C>T p.V296= | Silent (SNP) | VAF 145/413 reads (35%) | called by muse, mutect2, varscan2
- DOCK2 | c.1464C>G p.R488= | Silent (SNP) | VAF 63/283 reads (22%) | called by muse, mutect2, varscan2
- EFNA4 | c.576T>C p.L192= | Silent (SNP) | VAF 82/460 reads (18%) | catalogued as rs202221214; called by muse, mutect2, varscan2
- EHD3 | c.1011G>A p.E337= | Silent (SNP) | VAF 173/485 reads (36%) | called by muse, mutect2, varscan2
- FAM209A | c.240G>A p.E80= | Silent (SNP) | VAF 83/209 reads (40%) | called by muse, mutect2, varscan2
- FAT3 | c.8088C>A p.I2696= | Silent (SNP) | VAF 74/246 reads (30%) | called by muse, mutect2, varscan2
- GEMIN4 | c.2334C>T p.F778= | Silent (SNP) | VAF 125/219 reads (57%) | catalogued as rs1451608184; called by muse, mutect2, varscan2
- H2AX | c.381G>A p.P127= | Silent (SNP) | VAF 115/223 reads (52%) | called by muse, mutect2, varscan2
- HSF1 | c.57G>A p.L19= | Silent (SNP) | VAF 98/255 reads (38%) | catalogued as rs782766056; called by muse, mutect2, varscan2
- INSRR | c.3633G>T p.L1211= | Silent (SNP) | VAF 60/476 reads (13%) | called by muse, mutect2, varscan2
- IRX1 | c.975C>T p.S325= | Silent (SNP) | VAF 98/263 reads (37%) | called by muse, mutect2, varscan2
- KHDC1 | c.54C>T p.V18= | Silent (SNP) | VAF 67/232 reads (29%) | called by muse, mutect2, varscan2
- KLF18 | c.3006G>A p.T1002= | Silent (SNP) | VAF 90/202 reads (45%) | catalogued as rs540006283; called by muse, mutect2, varscan2
- LGR6 | c.1356G>A p.G452= (on ENST00000367278 / NM_001017403.1; = p.G400= on NM_021636.3) | Silent (SNP) | VAF 45/314 reads (14%) | called by muse, mutect2, varscan2
- LRRC14B | c.1362C>A p.I454= | Silent (SNP) | VAF 181/424 reads (43%) | called by muse, mutect2, varscan2
- MRPL24 | c.171C>T p.F57= | Silent (SNP) | VAF 153/559 reads (27%) | called by muse, mutect2, varscan2
- NEB | c.14832C>G p.L4944= | Silent (SNP) | VAF 110/281 reads (39%) | called by muse, mutect2, varscan2
- NUP210 | c.2922C>T p.Y974= | Silent (SNP) | VAF 113/312 reads (36%) | catalogued as rs553918791; called by muse, mutect2, varscan2
- OR1N2 | c.429C>T p.L143= | Silent (SNP) | VAF 129/284 reads (45%) | called by muse, mutect2, varscan2
- OR4C12 | c.787C>T p.L263= | Silent (SNP) | VAF 113/281 reads (40%) | catalogued as rs782526433; called by muse, mutect2, varscan2
- OR5M8 | c.51C>T p.T17= | Silent (SNP) | VAF 116/281 reads (41%) | called by muse, mutect2, varscan2
- P2RX2 | c.141C>T p.A47= | Silent (SNP) | VAF 136/314 reads (43%) | catalogued as rs760417852, COSV57684404; called by muse, mutect2, varscan2
- PGAP3 | c.792G>A p.Q264= | Silent (SNP) | VAF 198/467 reads (42%) | catalogued as rs1477897371; called by muse, mutect2, varscan2
- RIMS4 | c.42C>T p.F14= | Silent (SNP) | VAF 45/183 reads (25%) | catalogued as rs1014665258, COSV65719322, COSV65719408; called by muse, mutect2, varscan2
- RNF213 | c.2913C>G p.L971= | Silent (SNP) | VAF 100/271 reads (37%) | called by muse, mutect2, varscan2
- SACM1L | c.264A>G p.V88= | Silent (SNP) | VAF 112/278 reads (40%) | called by muse, mutect2
- SPRED2 | c.762C>T p.F254= | Silent (SNP) | VAF 173/456 reads (38%) | catalogued as rs749770464; called by muse, mutect2, varscan2
- SPTBN5 | c.5208G>A p.L1736= | Silent (SNP) | VAF 209/456 reads (46%) | called by muse, mutect2, varscan2
- SYNE2 | c.16653G>A p.L5551= | Silent (SNP) | VAF 118/297 reads (40%) | catalogued as COSV59943643; called by muse, mutect2, varscan2
- THRB | c.472C>A p.R158= | Silent (SNP) | VAF 74/309 reads (24%) | called by muse, mutect2, varscan2
- UNC13C | c.3210C>A p.S1070= | Silent (SNP) | VAF 85/271 reads (31%) | called by mutect2, varscan2
- VIL1 | c.2277C>T p.L759= | Silent (SNP) | VAF 153/408 reads (38%) | catalogued as COSV50288138; called by muse, mutect2, varscan2
- WRAP73 | c.486C>T p.I162= | Silent (SNP) | VAF 112/226 reads (50%) | catalogued as rs760371845; called by muse, mutect2, varscan2
- ZNF687 | c.2916C>T p.F972= | Silent (SNP) | VAF 73/378 reads (19%) | catalogued as rs1283947640; called by muse, mutect2, varscan2
- ATXN7 | c.*64C>T | 3'UTR (SNP) | VAF 64/230 reads (28%) | called by muse, mutect2, varscan2
- CD300LD | c.40+39C>T | Intron (SNP) | VAF 100/273 reads (37%) | catalogued as rs916785764, COSV60084414; called by muse, mutect2, varscan2
- CRELD1 | c.1049-401C>T | Intron (SNP) | VAF 95/341 reads (28%) | called by muse, mutect2, varscan2
- NPC2 | chr14:74476590 C>T | 3'Flank (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- RAF1 | c.834+621C>T | Intron (SNP) | VAF 136/295 reads (46%) | called by muse, mutect2, varscan2
- RCOR3 | chr1:211259572 G>C | 5'Flank (SNP) | VAF 72/222 reads (32%) | called by muse, mutect2, varscan2
- SRGAP2 | c.2358-723G>T | Intron (SNP) | VAF 141/380 reads (37%) | called by muse, mutect2, varscan2
